Surgical pathology report (de-identified scan), TCGA case TCGA-CR-5243, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-5243-01A (Primary Tumor).

[REDACTED]

[REDACTED]

[REDACTED]

FinalReport

DIAGNOSIS:1) TONSIL, LEFT, BIOPSY: MODERATELY TO POORLY DIFFERENTIATED INVASIVE SQUAMOUS CELL CARCINOMA.

[REDACTED]

CLINICAL DATA

Clinical Features: unspecified - [REDACTED]

Operation: unspecified

Operative Findings: unspecified

Operative Diagnosis: unspecified

Tissue Submitted: 1)left tonsil

GROSS DESCRIPTION:

1) SOURCE: Tonsil, Left. Received fresh is a 5 x 3 x 2 mm piece of tan-white hemorrhagic softtissue labeled left tonsil. The specimen is bisected and placed in one cassette and submitted en toto. Summary of sections: 1A, 2/1.

[REDACTED]

Slides and report reviewed by Attending Pathologist.

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 055a22cf-94d5-48a9-8920-66a23c93d9d3 (TCGA-CR-5243.FB07210C-6508-47BE-B6A3-5A9C18B22312.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).